Somatic mutation profile of tumor specimen 0DL6S5 from CCDI case PBBYYM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,493 days).
Specimen 0DL6S5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2f2782a-b2af-41d9-afc8-1dcd6258411d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bab5a66-0cd3-4a6a-b13b-3a074dcb66bf

The open-access MAF lists 6 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 2, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP2 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 58/804 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs762564041; called by muse, mutect2
- LRRIQ1 | c.2094T>C p.S698= | Silent (SNP) | VAF 46/249 reads (18%) | called by muse, mutect2, varscan2
- LTK | c.1524C>T p.A508= | Silent (SNP) | VAF 15/323 reads (5%) | called by muse, mutect2
- PLA2G6 | c.895-57C>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- PLB1 | c.556-29C>A | Intron (SNP) | VAF 16/560 reads (3%) | called by muse, mutect2
- SLC15A1 | c.*86C>A | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100919510; called by mutect2, varscan2
